Somatic mutation profile of tumor specimen 0DQOF5 from CCDI case PBCFHA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.0 years (714 days).
Specimen 0DQOF5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0a1d782-1d41-4c38-80b1-2bf74eebe610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQOEY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/930ecf60-5bad-48ae-af5a-e49712c129d4

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRSK2 | c.2116dup p.A706Gfs*121 | Frame Shift Ins (INS) | VAF 72/504 reads (14%) | called by pindel, varscan2
- PATZ1 | c.372C>T p.S124= | Silent (SNP) | VAF 32/348 reads (9%) | catalogued as COSV53228922; called by muse, mutect2
